Somatic mutation profile of tumor specimen 0DJM9A from CCDI case PBBXCU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.4 years (4,535 days).
Specimen 0DJM9A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c53c888-c721-4393-89b4-181a9264a76f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd7f820d-d1f5-481f-90f6-e74fd37a67d3

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 48/792 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs769150403; called by muse, mutect2
- DNAH14 | c.4690A>G p.N1564D (on ENST00000445597; = p.N1969D on NM_001367479.1) | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEB | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 327/950 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OTUD1 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 50/634 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SUPT3H | c.687G>A p.M229I (on ENST00000371460 / NM_181356.3; = p.M218I on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/726 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR51S1 | c.345T>C p.F115= | Silent (SNP) | VAF 19/735 reads (3%) | called by muse, mutect2
